Gene-level copy-number profile of tumor specimen TCGA-13-0801-01A from TCGA case TCGA-13-0801, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 46.0 years (16,812 days).
Specimen TCGA-13-0801-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0905aeaa-d338-426f-ac9b-9550cdbd54d8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0801-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/189737b9-68da-4552-9a14-d6650e86ca6f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 41; copy number 2: 20,560; copy number 3: 3,324; copy number 4: 27,803; copy number 5: 866; copy number 6: 6,481; copy number 7: 31; copy number 8: 485; copy number 9: 166; copy number 11: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-13-0801-01): tumor purity 0.86, ploidy 1.78, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:40,187,170–40,811,184, 13 genes: AC095057.4, RHOH, AC095057.2, LINC02265, CHRNA9, RNU7-74P, RBM47, AC098869.2, AC098869.1, MIR4802, AC131953.2, NSUN7, ARL4AP2.
- chr4:40,812,779–40,826,765, 2 genes: AC131953.1, Y_RNA.
- chr5:138,868,921–139,384,553, 16 genes (within-gene range 0–2): LRRTM2, SIL1, RNA5SP194, AC011405.1, RPL12P21, RNU6-572P, MATR3, SNHG4, SNORA74D, SNORA74A, MATR3, RNA5SP195, RN7SKP64, PAIP2, AC135457.1, SLC23A1.
- chr10:87,817,928–88,049,823, 8 genes: CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.
- chr12:124,593,181–124,638,444, 4 genes: AC073592.8, AC073592.2, AC073592.10, AC073592.4.
- chr18:61,748,082–61,894,247, 2 genes (within-gene range 0–2): LINC01544, RNF152.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 181 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:139,389,761–140,577,397, 14 genes, copy number 11 (within-gene range 6–11): AC046134.2, RBP2, AC097103.1, ACTG1P1, RBP1, NMNAT3, AC046134.1, RN7SKP124, RN7SL724P, AC110716.2, AC110716.1, AC016933.1, TRMT112P5, CLSTN2.
- chr3:169,003,022–169,038,416, 1 gene, copy number 11: LINC01997.
- chr3:193,593,144–193,697,811, 1 gene, copy number 9 (within-gene range 6–9): OPA1.
- chr3:193,740,471–198,222,513, 165 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 29. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
